Surgical pathology report (de-identified scan), TCGA case TCGA-60-2708, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2708-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT*******Addendum*******

SPECIMEN(S): A. 4R LYMPH NODE
B. 4L LYMPH NODE
C. LEVEL 7 LYMPH NODE
D. LEFT LOWER LOBE LUNG
E. ADDITIONAL BRONCHIAL MARGIN
F. ADDITIONAL BRONCHIAL MARGIN
G. LEFT MIDDLE LOBE
H. LEVEL V LYMPH NODE
I. LEVEL VII LYMPH NODE
J. FINAL PNEUMONECTOMY BRONCHIAL MARGIN
K. LEVEL VI LYMPH NODE

CLINICAL HISTORY:

None

PRE-OPERATIVE DIAGNOSIS:

Left lower lobe lung ca.

FROZEN SECTION DIAGNOSIS:

FSA, FSB, FSC: No tumor seen by [REDACTED] called to [REDACTED]

FSE: Moderate squamous dysplasia, negative for malignancy by [REDACTED] called to [REDACTED]

FSF: Negative for dysplasia by [REDACTED] called [REDACTED]

GROSS DESCRIPTION:**A. 4R LYMPH NODE**

Received fresh for intra-operative consultation are two tan fragments of soft tissue each measuring 0.3cm. in greatest dimension. The specimen is entirely submitted for frozen section and in one cassette labelled FSA after formalin fixation.

[REDACTED]

[page 2 of 6]
[REDACTED]

B. 4L LYMPH NODE

Received fresh for intra-operative consultation is one tan grey fragment of soft tissue measuring 0.9x0.5x0.3cm. The entire specimen is entirely submitted for frozen section and in one cassette labelled FSB after formalin fixation.

C. LEVEL 7 LYMPH NODE

Received fresh for intra-operative consultation are two tan black fragments of soft tissue measuring 0.9x0.4x0.2cm. and 0.7x0.4x0.2cm. The entire specimen is entirely submitted for frozen section and in one cassette labelled FSC after formalin fixation.

FSA-FSC: Each portion contains portion of tan black to tan grey lymphoid tissue.

D. LEFT LOWER LOBE LUNG

Received fresh for intra-operative consultation is a 291gm. 16.0x14.0x6.5cm. lobectomy specimen. The hilum shows a tan white firm mass protruding through the bronchus. The hilar tissue is firmly adhered to the mass. The pleura is purple grey, smooth. On section, there is a 6.5x6.5x5.5cm. firm, tan, solid to cystic, partially necrotic mass with green mucus. The tumor is located centrally and extends into the main stem bronchus. The adjacent lung parenchyma shows impacted mucous and foci of honeycombing and consolidation. The lung parenchyma at the base is pink red and spongy. The pleura is marked by black ink at the mass. Representative tissue is submitted in eleven cassettes as follows:

- D1: bronchus at hilum and three possible hilar lymph nodes
- D2: vascular margins at hilum and two possible lymph nodes
- D3: tumor at bronchus and three possible lymph nodes
- D4-D5: mass with pleura
- D6: mass
- D7: mass with adjacent lung
- D8: lung with impacted mucin
- D9: lung, honeycombed area
- D10: consolidated area of lung
- D11: random section of uninvolved lung at base

E. ADDITIONAL BRONCHIAL MARGIN

Received fresh for intra-operative consultation are two tan fragments of bronchial tissue measuring 1.2x0.4x0.1cm. and 1.0x0.3x0.1cm. A stitch on each fragment designates the true margin. The margins are shaved from the pieces and submitted for frozen section.

Representative tissue is submitted in one cassette labelled FSE after formalin fixation.

F. ADDITIONAL BRONCHIAL MARGIN

Received fresh for intra-operative consultation is a 0.4x0.2x0.1cm. tan fragment of bronchial tissue with a stitch indicating the true margin. The entire specimen is submitted for frozen section (en face) and in one cassette labelled FSF after formalin fixation.

G. LEFT MIDDLE LOBE

Received fresh is a 164gm 16.0x9.0x2.5cm. lobe of lung. The hilum shows a 2.5cm. in length portion of pulmonary artery. On serial sectioning, the parenchyma is pink red and spongy with no discrete lesion. Multiple hilar lymph nodes are identified. Representative tissue is submitted in five cassettes as follows:

- G1: bronchial margin, en face and seven possible hilar lymph nodes
- [REDACTED]

[page 3 of 6]
- G2: four hilar lymph nodes, one bisected and inked black
G3: one hilar lymph node
G4: lung with intraparenchymal lymph node
G5: random section of lung

H. LEVEL V LYMPH NODE

Received in formalin are three tan grey to black fragments of soft tissue measuring 0.2cm., 0.4cm, and 1.0x0.7x0.3cm. The entire specimen is submitted in one cassette labelled H1.

I. LEVEL VII LYMPH NODE

Received in formalin are five fragments of tan grey black soft tissue ranging in size from 0.5cm to 1.7x1.0x0.5cm. On section, the cut surface of the largest lymph node is pink tan, grey black, soft and homogenous. The entire specimen is submitted in two cassettes as follows:

I1: four lymph nodes

I2: one lymph node, bisected

J. FINAL PNEUMONECTOMY BRONCHIAL MARGIN

Received in formalin is a 2.2x1.0x0.2cm. portion of bronchus with a stitch at the final margin. The bronchial mucosa is pink red and hemorrhagic. The bronchial margin measures 0.9cm. in diameter. It is inked black. Representative tissue is submitted in one cassette labelled J1 including the bronchial margin (en face) and random longitudinal sections of the bronchus.

K. LEVEL VI LYMPH NODE

Received in formalin are two tan grey black yellow fragments of soft tissue measuring 1.2x0.6x0.5cm. and 1.2x1.0x0.7cm. On section, the cut surface shows grey black focally pink, homogenous soft parenchyma. The entire specimen is submitted in one cassette (larger lymph node inked black).

DIAGNOSIS:

A. LYMPH NODE, 4R, EXCISION:

FRAGMENTS OF LYMPH NODE, NEGATIVE FOR METASTASIS.

B. LYMPH NODE, 4L, EXCISION:

ONE ANTHRACOTIC LYMPH NODE, NO TUMOR SEEN (0/1).

C. LYMPH NODE, LEVEL 7, EXCISION:

FRAGMENTS OF LYMPH NODE, NEGATIVE FOR METASTASIS.

D. LUNG, LEFT LOWER LOBE, LOBECTOMY:

INVASIVE NON-KERATINIZING SQUAMOUS CELL CARCINOMA, MODERATE TO POORLY DIFFERENTIATED WITH CLEAR CELL FEATURES

-TUMOR SIZE: 6.5x6.5x5.5 CM

-TUMOR INVADES THE MAIN STEM BRONCHUS

-ASSOCIATED SQUAMOUS CELL CARCINOMA IN-SITU.

-ANGIOLYMPHATIC PERINEURAL INVASION ABSENT

-VISCERAL PLEURA FREE OF TUMOR.

-METASTATIC CARCINOMA TO ONE OF ELEVEN HILAR LYMPH NODES (1/11)

[page 4 of 6]
-INVASIVE CARCINOMA INVOLVES HILAR ADIPOSE TISSUE.
-UNINVOLVED LUNG SHOWS EMPHYSEMA AND MARKED MUCOUS SECRETION.

- E. LUNG, LEFT, ADDITIONAL BRONCHIAL MARGIN, EXCISION:
BRONCHIAL MUCOSA WITH FOCAL DYSPLASIA, NO TUMOR SEEN.
- F. LUNG, LEFT, ADDITIONAL BRONCHIAL MARGIN, EXCISION:
BRONCHIAL MUCOSA, NO TUMOR SEEN.
- G. LUNG, LEFT MIDDLE LOBE, LOBECTOMY:
-EXTENSIVE PATCHY INTERSTITIAL FIBROSIS.
-EMPHYSEMATOUS CHANGES.
-TWELVE HILAR LYMPH NODES, NEGATIVE FOR METASTASIS (0/12).
-NO TUMOR SEEN.
- H. LYMPH NODE, LEVEL V, EXCISION:
FRAGMENTS OF LYMPH NODES, NO TUMOR SEEN.
- I. LYMPH NODES, LEVEL VII, EXCISION:
ELEVEN LYMPH NODES, NEGATIVE FOR METASTASIS (0/11).
- J. FINAL PNEUMONECTOMY BRONCHIAL MARGIN, EXCISION:
BRONCHIAL MUCOSA WITH ULCERATION AND ACUTE INFLAMMATION.
-NO TUMOR SEEN.
- K. LYMPH NODE, LEVEL VI, EXCISION:
TWO LYMPH NODES, NEGATIVE FOR METASTASIS (0/2).

Lung template

1. Tumor type: Squamous cell carcinoma, non keratinizing
2. Histologic grade: Moderately to poorly differentiated
3. Tumor location: Central
4. Tumor size: 6.5x6.5x5.5 cm.
5. Angiolymphatic invasion: Absent
6. Perineural invasion: Absent
7. Involvement of main stem bronchus: Present
8. Bronchial margin: Negative
9. Visceral pleural margin: Negative
10. Hilar lymph nodes: Positive (1/11)
11. In-situ carcinoma: Present
12. Pathologic stage: pT3 N1 MX
13. Non-neoplastic lung: Emphysematous changes
-

[page 5 of 6]
ADDENDUM:

In discussion with specimen G which was received labeled "left middle lobe" most likely represents the left upper lobe.

Additionally, the tumor present in the left lower lobe (specimen D), invades the left lower lobe bronchus and NOT the main stem bronchus.

[page 6 of 6]
ADDENDUM:

As mentioned in the previous addendum, the tumor does not invade the main stem bronchus.
The following template is revised to reflect the correct pathologic stage: **pT2N1Mx**.

Lung template (non-small cell lung cancer)

Surgical procedure:	Pneumonectomy
Tumor location:	Central
	LLL
Tumor size (greatest diameter):	6.5X6.5X5.5CM.
Tumor type:	squamous cell carcinoma
Histologic grade:	moderate to poorly differentiated
Angiolymphatic invasion:	absent
Bronchial margin (including distance from tumor):	negative
Visceral pleural involvement :	absent
Satellite tumor(s) :	no
Lymph node involvement:	Peribronchial Positive (1/11)
	Mediastinal Negative (0/17)

AJCC stage: **pT2N1MX**

Non-neoplastic lung: emphysema

Source: NCI Genomic Data Commons file 40b5c8c8-6a6c-478a-806b-37cf3fc06e4b (TCGA-60-2708.7F0ED176-146A-4EA2-8F39-36D402D74757.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).